Somatic mutation profile of tumor specimen TCGA-F7-A61S-01A (aliquot TCGA-F7-A61S-01A-11D-A28R-08) from TCGA case TCGA-F7-A61S, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G1; Age at diagnosis: 62.0 years (22,655 days).
Specimen TCGA-F7-A61S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cefbc945-6f38-4340-8de7-2ed9c4b08e13.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F7-A61S-10A (Blood Derived Normal), aliquot TCGA-F7-A61S-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78f52e59-cd52-445e-b59c-b3db815da88f

The open-access MAF lists 116 somatic variants for this specimen: 86 protein-altering or splice-affecting, 27 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 27, Nonsense Mutation 6, Frame Shift Ins 4, Frame Shift Del 4, Splice Site 3, RNA 2, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 32/76 reads (42%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 31/81 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC8 | c.2629C>T p.R877W | Missense Mutation (SNP) | VAF 37/158 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); catalogued as rs752953495, COSV56848160; called by muse, mutect2, varscan2
- ACSM3 | c.1436A>T p.D479V | Missense Mutation (SNP) | VAF 47/160 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55500842, COSV99184554; called by muse, mutect2, varscan2
- AFF3 | c.2956C>T p.R986* | Nonsense Mutation (SNP) | VAF 24/151 reads (16%) | catalogued as rs1469868233, COSV57854798, COSV57875429; called by muse, mutect2, varscan2
- AGXT2 | c.1535G>A p.R512K | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99183768; called by muse, mutect2, varscan2
- AHNAK | c.6373C>A p.H2125N | Missense Mutation (SNP) | VAF 95/384 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs754692608, COSV57203375; called by muse, mutect2, varscan2
- ALG12 | c.1208C>A p.S403Y | Missense Mutation (SNP) | VAF 11/54 reads (20%) | PolyPhen probably damaging (0.999); catalogued as COSV100427117; called by muse, mutect2, varscan2
- ANKRD11 | c.5270C>T p.S1757F | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1406602469, COSV99969632; called by muse, mutect2, varscan2
- ARSI | c.769A>T p.N257Y | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100156011; called by muse, mutect2, varscan2
- CACTIN | c.1273A>T p.I425F | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99698596; called by muse, mutect2
- CCDC71 | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as rs945805555, COSV100422375; called by muse, mutect2, varscan2
- CCNF | c.251C>T p.S84F | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99563737; called by muse, mutect2, varscan2
- CD40 | c.484C>T p.H162Y | Missense Mutation (SNP) | VAF 92/241 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as COSV64848024; called by muse, mutect2, varscan2
- CDC42BPA | c.2830A>G p.I944V | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100504171; called by muse, mutect2
- CER1 | c.613T>A p.S205T | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV101097838; called by muse, mutect2, varscan2
- CLCC1 | c.1473C>G p.S491R (on ENST00000356970 / NM_001377464.1; = p.S441R on NM_015127.5) | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV99915328; called by muse, mutect2, varscan2
- COL17A1 | c.203-1G>A p.X68_splice | Splice Site (SNP) | VAF 15/114 reads (13%) | catalogued as rs111607386, COSV100793191; called by muse, mutect2, varscan2
- DCAF1 | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV100244507; called by muse, mutect2
- DHX16 | c.446+1G>A p.X149_splice | Splice Site (SNP) | VAF 47/210 reads (22%) | catalogued as COSV100906097, COSV64582377; called by muse, mutect2, varscan2
- ENTR1 | c.495G>T p.E165D (on ENST00000357365 / NM_001039707.2; = p.E142D on NM_006643.4) | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.147); catalogued as COSV100048208; called by muse, mutect2, varscan2
- F13A1 | c.1808C>T p.A603V | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs148207995, COSV53561205; called by muse, mutect2, varscan2
- FARP1 | c.3010T>C p.S1004P | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100130911; called by muse, mutect2
- FAT1 | c.8785G>T p.E2929* | Nonsense Mutation (SNP) | VAF 15/79 reads (19%) | catalogued as COSV101499397; called by muse, mutect2, varscan2
- FBXL7 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61653742; called by muse, mutect2, varscan2
- FGG | c.5G>A p.S2N | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV100271914; called by muse, mutect2, varscan2
- FHDC1 | c.889T>A p.L297M | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99471351; called by muse, mutect2, varscan2
- GAS2L1 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs771375346, COSV53330328, COSV99329552; called by muse, mutect2, varscan2
- GIGYF2 | c.596C>G p.S199* | Nonsense Mutation (SNP) | VAF 20/96 reads (21%) | catalogued as COSV101004412, COSV65249374; called by muse, mutect2, varscan2
- HSPG2 | c.7417C>T p.R2473C | Missense Mutation (SNP) | VAF 41/205 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.954); catalogued as rs757787338, COSV101020748; called by muse, mutect2, varscan2
- IRAG1 | c.1882C>T p.R628C | Missense Mutation (SNP) | VAF 64/270 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773760936, COSV70210927; called by muse, mutect2, varscan2
- ITPK1 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.605); catalogued as COSV50901098, COSV99968939; called by muse, mutect2, varscan2
- KIF2B | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs181862662; called by muse, mutect2, varscan2
- LRRC31 | c.1553T>A p.I518K | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV99246770; called by muse, mutect2, varscan2
- LRRIQ4 | c.1069A>T p.T357S | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.71); PolyPhen benign (0.319); catalogued as COSV100540265, COSV61618601; called by muse, mutect2, varscan2
- MAP3K1 | c.1423+1G>T p.X475_splice | Splice Site (SNP) | VAF 14/63 reads (22%) | catalogued as COSV101266817, COSV101267100; called by muse, mutect2, varscan2
- MDC1 | c.4190A>T p.N1397I | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.019); catalogued as COSV100902851; called by muse, mutect2, varscan2
- MGAT4C | c.825T>G p.F275L | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59838650; called by muse, mutect2, varscan2
- MPP7 | c.851G>T p.R284M | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100517472, COSV61736151; called by muse, mutect2, varscan2
- MTUS2 | c.371C>T p.T124M | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.047); catalogued as rs745418801, COSV70917869, COSV70920544; called by muse, mutect2, varscan2
- MYH6 | c.270G>T p.M90I | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.691); catalogued as COSV100676663; called by muse, mutect2, varscan2
- NAALADL1 | c.1271C>T p.T424M | Missense Mutation (SNP) | VAF 26/190 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs372854698, COSV100368110; called by muse, mutect2, varscan2
- NBEAL1 | c.5401C>G p.L1801V | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as COSV101495712; called by muse, mutect2, varscan2
- NIN | c.5470A>T p.T1824S (on ENST00000382041 / NM_182946.1; = p.T1111S on NM_016350.4) | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV99813781; called by muse, mutect2, varscan2
- NINL | c.3164A>G p.K1055R | Missense Mutation (SNP) | VAF 57/126 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.031); catalogued as COSV99625515; called by muse, mutect2, varscan2
- OR1A2 | c.95dup p.L32Ffs*21 | Frame Shift Ins (INS) | VAF 62/137 reads (45%) | catalogued as rs748774437; called by mutect2, varscan2
- PAK2 | c.7G>C p.D3H | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.708); catalogued as COSV100506165; called by muse, mutect2
- PAK6 | c.1841G>A p.R614Q | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs143844489; called by muse, mutect2, varscan2
- PAPOLB | c.1093G>A p.A365T | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as COSV101271454; called by muse, mutect2, varscan2
- PCDHB14 | c.596C>G p.A199G | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.03); catalogued as rs564196616, COSV99506002; called by muse, mutect2, varscan2
- PCDHB6 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs1554277390, COSV50714232; called by muse, mutect2, varscan2
- PCDHGA12 | c.2093C>A p.A698D | Missense Mutation (SNP) | VAF 58/285 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as COSV99340550; called by muse, mutect2, varscan2
- PGLYRP1 | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs758664311, COSV99151506; called by muse, mutect2, varscan2
- PHLPP1 | c.3134A>G p.Y1045C | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1208149441, COSV99408457; called by muse, mutect2, varscan2
- PRTG | c.2554C>G p.R852G | Missense Mutation (SNP) | VAF 16/173 reads (9%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.759); catalogued as COSV101221402, COSV66838324, COSV66839097; called by muse, mutect2
- PTCH1 | c.1624A>T p.K542* | Nonsense Mutation (SNP) | VAF 7/38 reads (18%) | catalogued as COSV100108876; called by muse, mutect2, varscan2
- PTPRC | c.319C>T p.P107S | Missense Mutation (SNP) | VAF 53/175 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV100722739, COSV61421309; called by muse, mutect2, varscan2
- ROBO2 | c.2395G>A p.V799I | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.396); catalogued as rs759802937, CM137439, COSV59930603; called by muse, mutect2, varscan2
- RTN4 | c.1205A>G p.D402G | Missense Mutation (SNP) | VAF 37/194 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100463317; called by muse, mutect2, varscan2
- RYR3 | c.10381G>A p.E3461K (on ENST00000389232; = p.E3462K on NM_001036.6) | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as rs780070006, COSV101211697, COSV66807183; called by muse, mutect2, varscan2
- SCAMP3 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV56944054; called by muse, mutect2, varscan2
- SPINT1 | c.1561G>T p.V521F (on ENST00000344051 / NM_181642.3; = p.V505F on NM_003710.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/224 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.132); catalogued as COSV100689079; called by muse, mutect2, varscan2
- SYNE3 | c.719T>C p.V240A | Missense Mutation (SNP) | VAF 50/212 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.114); catalogued as rs752402746, COSV100516100; called by muse, mutect2, varscan2
- TBC1D9 | c.3619C>T p.R1207W | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.586); catalogued as rs754331118, COSV71307494; called by muse, mutect2, varscan2
- TMEM252 | c.299C>A p.A100D | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV101051124; called by muse, mutect2, varscan2
- TRAK2 | c.1994C>T p.S665L | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as rs373635648; called by muse, mutect2, varscan2
- TRARG1 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 30/232 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.229); catalogued as rs370410748, COSV61563388; called by muse, mutect2, varscan2
- TUBA3D | c.544G>A p.V182M | Missense Mutation (SNP) | VAF 37/385 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV100342632; called by muse, mutect2, varscan2
- TUBA3E | c.544G>A p.V182M | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as COSV99919851; called by muse, mutect2, varscan2
- UGT2B10 | c.241A>G p.T81A | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.143); catalogued as COSV99608391; called by muse, mutect2, varscan2
- UTP25 | c.1319C>G p.A440G | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV101504747; called by muse, mutect2, varscan2
- VPS54 | c.1925T>C p.M642T | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV99708219; called by muse, mutect2, varscan2
- ZCCHC9 | c.382A>G p.M128V | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as rs746315529, COSV99562656; called by muse, mutect2, varscan2
- ZNF24 | c.642A>C p.E214D | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs1360764284, COSV99734308; called by muse, mutect2, varscan2
- ZNF615 | c.1072C>T p.R358C | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.787); catalogued as rs748566184, COSV65034387; called by muse, mutect2, varscan2
- ZNF638 | c.3352G>A p.D1118N | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.227); catalogued as COSV100039036; called by muse, mutect2, varscan2
- C21orf91 | c.328del p.S110Lfs*38 | Frame Shift Del (DEL) | VAF 18/99 reads (18%) | called by mutect2, pindel, varscan2
- C6orf89 | c.920_921del p.V307Gfs*58 (on ENST00000373685; = p.V314Gfs*58 on NM_152734.4) | Frame Shift Del (DEL) | VAF 10/70 reads (14%) | called by pindel, varscan2
- FAT1 | c.3514_3534del p.D1172_I1178del | In Frame Del (DEL) | VAF 12/44 reads (27%) | called by mutect2, pindel
- IPO8 | c.1631dup p.M544Ifs*9 | Frame Shift Ins (INS) | VAF 7/31 reads (23%) | called by mutect2, pindel, varscan2
- KMT2D | c.12763_12773del p.G4255Lfs*75 | Frame Shift Del (DEL) | VAF 11/76 reads (14%) | called by mutect2, pindel
- MC2R | c.711del p.H238Mfs*4 | Frame Shift Del (DEL) | VAF 21/93 reads (23%) | called by mutect2, pindel, varscan2
- SLC39A10 | c.240dup p.G81Wfs*18 | Frame Shift Ins (INS) | VAF 15/90 reads (17%) | called by mutect2, pindel, varscan2
- STMN3 | c.374dup p.N125Kfs*2 | Frame Shift Ins (INS) | VAF 8/50 reads (16%) | called by mutect2, pindel, varscan2
- ZNF513 | c.1073_1078dup p.G359_F360ins* | Nonsense Mutation (INS) | VAF 33/156 reads (21%) | called by mutect2, pindel, varscan2
- ASTN1 | c.1995C>T p.L665= | Silent (SNP) | VAF 14/104 reads (13%) | catalogued as COSV99921999; called by muse, mutect2, varscan2
- CDH10 | c.2190C>T p.Y730= | Silent (SNP) | VAF 34/129 reads (26%) | catalogued as rs542487965, COSV52574109; called by muse, mutect2, varscan2
- DDB1 | c.3354C>T p.S1118= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV100074633; called by muse, mutect2, varscan2
- DMD | c.3006T>A p.T1002= | Silent (SNP) | VAF 13/21 reads (62%) | catalogued as COSV100820132; called by muse, mutect2, varscan2
- ECT2L | c.1749G>A p.Q583= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as COSV100872004; called by muse, mutect2, varscan2
- EDNRB | c.585G>A p.T195= (on ENST00000377211 / NM_001201397.1; = p.T105= on NM_000115.5) | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV100526733, COSV57529335; called by muse, mutect2, varscan2
- EPS15 | c.2286C>T p.V762= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as COSV100869554; called by muse, mutect2, varscan2
- FAM47B | c.1098C>T p.G366= | Silent (SNP) | VAF 26/41 reads (63%) | catalogued as COSV100264376; called by muse, mutect2, varscan2
- HNF4G | c.114C>T p.R38= (on ENST00000354370 / NM_001330561.2; = p.R85= on NM_004133.5) | Silent (SNP) | VAF 24/106 reads (23%) | catalogued as rs775584845, COSV100584581; called by muse, mutect2, varscan2
- INPP5D | c.2661C>T p.H887= (on ENST00000445964 / NM_001017915.3; = p.H886= on NM_005541.5) | Silent (SNP) | VAF 28/140 reads (20%) | catalogued as rs768413369, COSV64038167; called by muse, mutect2, varscan2
- IRF7 | c.822A>T p.P274= (on ENST00000397566; = p.P261= on NM_001572.5) | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV99201372; called by muse, mutect2, varscan2
- KDM2B | c.3150C>A p.P1050= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as COSV100997444; called by muse, mutect2, varscan2
- KPNA1 | c.1503G>A p.E501= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as COSV100724242; called by muse, mutect2, varscan2
- LDHAL6B | c.492C>T p.A164= | Silent (SNP) | VAF 42/165 reads (25%) | catalogued as COSV99895766; called by muse, mutect2, varscan2
- MED16 | c.1011C>G p.L337= | Silent (SNP) | VAF 12/120 reads (10%) | catalogued as COSV54131194; called by muse, mutect2
- MPRIP | c.1839C>T p.R613= | Silent (SNP) | VAF 62/118 reads (53%) | catalogued as COSV100505841; called by muse, mutect2, varscan2
- MTPAP | c.27G>A p.L9= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV99554131; called by muse, mutect2, varscan2
- PPP6R2 | c.279C>T p.S93= | Silent (SNP) | VAF 135/243 reads (56%) | catalogued as rs777425517, COSV99324342; called by muse, mutect2, varscan2
- PTGIS | c.1479C>G p.P493= | Silent (SNP) | VAF 21/84 reads (25%) | catalogued as rs756114643, COSV99721045, COSV99721412; called by muse, mutect2, varscan2
- RIF1 | c.1686A>G p.K562= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV54618824, COSV99690669; called by muse, mutect2, varscan2
- RPRD2 | c.4182C>T p.S1394= | Silent (SNP) | VAF 17/97 reads (18%) | catalogued as COSV100955111; called by muse, mutect2, varscan2
- SLC3A2 | c.1743C>T p.S581= | Silent (SNP) | VAF 34/180 reads (19%) | catalogued as rs143862119; called by muse, mutect2, varscan2
- TAAR9 | c.219G>A p.S73= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as rs1478177458, COSV101453275, COSV101453354; called by muse, mutect2, varscan2
- TASOR2 | c.894A>C p.G298= | Silent (SNP) | VAF 34/131 reads (26%) | catalogued as COSV100050570; called by muse, mutect2, varscan2
- UNC13C | c.3339G>A p.E1113= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as rs765767018, COSV99518402; called by muse, mutect2, varscan2
- ZDHHC15 | c.354G>A p.P118= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV100973795; called by muse, mutect2, varscan2
- ZFPM1 | c.2892G>T p.T964= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as COSV100128492, COSV60325841; called by muse, mutect2, varscan2
- ARPC5 | c.*2C>G | 3'UTR (SNP) | VAF 33/190 reads (17%) | catalogued as rs1381197648, COSV99664839; called by muse, mutect2, varscan2
- FAM27E5 | n.239C>A | RNA (SNP) | VAF 30/109 reads (28%) | called by muse, mutect2, varscan2
- UBTFL2 | n.757C>T | RNA (SNP) | VAF 11/44 reads (25%) | catalogued as rs371476605; called by mutect2, varscan2
